CCDI case PBCCRY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ac1e7459-2e43-4e05-a38d-cbf82c6f8843

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pleomorphic xanthoastrocytoma: ICD-O-3 morphology code: 9424/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.8 years (1,030 days).

Biospecimens (3 samples)
- Sample 0DOG32: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DOG3L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DOG3W: Tissue type: Tumor; Specimen type: Solid Tissue.
